Surgical pathology report (de-identified scan), TCGA case TCGA-HW-A5KL, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-A5KL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: F

Gender:

Ref. Physician:

Patient Address:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

ear old female with right temporal tumor.

Specimens Submitted:

1: Right temporal lobe lesion (fs)

2: Right temporal lobe and brain lesion

DIAGNOSIS:

1,2 Brain, right temporal lobe; resection:

-Diffusely infiltrating astrocytoma (see note)

Note: While two mitotic figures are seen in the intraoperative smear preparation (a finding that is worrisome for anaplasia), the tissue sections demonstrate an astrocytoma at the WHO grade II level. The MIB-1 labeling index is not elevated (does not exceed 2%). Many tumor cells label for p53, and a subset express R132H mutant IDH1.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

MOL MGMT

P53

P53

IDH1-H09

IDH1-H09

IDH1-H09

IDH1-H09

NEG CONT

NEG CONT

NEG CONT

IMM RECUT

IMM RECUT

IMM RECUT

MIB-1 (Ki-67)

MIB-1 (Ki-67)

Comment

ICD-O-3
Astrocytoma, diffus + 9400/3
Site: Path. Brain, temporal lobe
C71.2
CCF- Brain, supratentorial
NOS
9/11/13 C71.0

Gross Description:

1)The specimen is received fresh for frozen section consultation, labeled " Right temporal lobe lesion " and consists of a piece of soft tan tissue measuring 1 x 1 x 02 cm. The specimen is entirely submitted for frozen section and touch prep.

[page 2 of 2]
Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "Right temporal lobe and brain lesion" and consists of a 2.9 x 1.5 x 0.9 cm fragment of focally hemorrhagic, tan-pink to white brain tissue. A portion of tissue is submitted for TPS and the remaining specimen is entirely submitted for permanent.

Summary of sections:
RT -- right temporal lobe brain lesion

Summary of sections:
Part 1: Right temporal lobe lesion (fs)

Sect.	Site	PCs
fsc		1

Part 2: Right temporal lobe and brain lesion

Block	S:	PCs
1	Ac	0
2	RT	

Intraoperative

Note: The diagnosis in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Right temporal lobe lesion (fs): Infiltrating astrocytoma. Mitotic activity seen on smear preparation. (HUSE)
PERMANENT DIAGNOSIS: Same

Source: NCI Genomic Data Commons file 9ea3ae19-6b8c-4f82-8d24-16972fd2a67a (TCGA-HW-A5KL.759EB3D5-8901-4476-8831-22B0BD976778.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).